Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A8C4, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A8C4-01A (Primary Tumor).

[page 1 of 2]
---SURGICAL PATHOLOGY CONSULTATION--- (Accession

Status: Final result

Results:

Collection Information

Consentment: Collection Date: Collection Time: Collected By: Specimen Source: Specimen Description:

Component Results

Component

DIAGNOSIS

Soft tissue, right lower leg, resection:
High grade spindle cell sarcoma with extensive tumor necrosis (40%),
21.0 cm, present at inked (blue and black) resection margins; see
comment.
Mitotic count: up to 40 per high power field.

Date reported:

Pathologist (Electronic Signature)

COMMENT

The patient's prior biopsy was concurrently
reviewed and selected immunohistochemical stained were performed on the
resection specimen. Rare tumor cells are positive for desmin and calponin.
Myogenin stain is negative. Although this tumor likely arose in
myxofibrosarcoma, pleomorphic sarcoma has overgrown any recognizable lower
grade component.

HISTORY

TISSUE SUBMITTED

A. Right lower leg tumor

GROSS

Specimen condition: Received fresh in a container labeled with the
patient's name, hospital number and "Right lower leg tumor" is a 23.0 x
15.0 x 7.0 cm soft tissue resection specimen. The mass is covered on
one surface by a thin layer of red-brown skeletal muscle and fascia.
The remaining tissue is composed of a pink-tan, multilobulated, friable
exposed mass, consistent with tumor. Also received is a detached
aggregate of skeletal muscle and detached tumor measuring 13.0 x 10.5 x
2.0 cm in aggregate. Type of procedure: Resection.
Overall size: The tumor measures 21.0 x 15.0 x 6.5 cm.

Types of identifiable tissue present and size of each: The majority of
the specimen is composed of tumor with a thin rim of overlying skeletal
muscle and fascia along one surface.

Attached organs: None.

Tumor gross morphologic description: The tumor mass is tan-pink,
multilobulated and friable. Sectioning reveals slightly gelatinous cut
surfaces with focal areas of cystic degeneration and necrosis
(approximately 30%-40%). The tumor is grossly exposed along all
surfaces not covered by skeletal muscle.

Size: 21.0 x 15.0 x 6.5 cm.

Depth of tumor: Unable to assess.

Estimate % necrosis: 30-40%.

Previous biopsy site/scar: Not identified.

Involvement/invasion of major structures: The tumor grossly abuts the
fascial/muscular surface.

Presence of satellite nodules away from main mass: Not identified.

Lymph nodes, if present: None present.

Margins: The tumor grossly involves all surfaces not covered by skeletal
muscle/fascia. The tumor grossly abuts the skeletal muscle/fascial
surface.

Photograph: None taken.

Tissue saved for special studies: This case is consented and a portion of
the tumor is submitted to the tissue bank.

Ink identifiers by pathologist: Muscle/fascial surface=black, remainder
of resection margins=blue.

Blocks submitted: A1-A4, representative sections of tumor in relationship
to fascial surface/skeletal muscle (inked black); A5, tumor in
relationship to exposed soft tissue margins (inked blue); A6-A15,
additional representative sections of mass, two per cassette.

MICROSCOPIC

Tumor microscopic description:

Histologic type: Spindle cell sarcoma.

Histologic grade: High grade.

Mitotic rate (per 10 hpf @ 40X): up to 40 per 10 high power fields.

Extent of necrosis: Present, approximately 40%.

Vascular invasion: Not identified.

Inflammatory infiltrate: Not present.

Site and depth: Unable to access.

Maximal dimension: 21.0 cm.

Minimal distance(s) to resection margins: All resection margins are
involved, including the skeletal/fascial surface.

Character of lesion/margin: Infiltrative.

Evidence of pre-existing benign lesion: Not identified.

Lymph nodes: None identified.

Special studies: Immunohistochemical stains were performed; see comment.

ICD-O-3

Sarcoma, pleomorphic,
undifferentiated 8862/3

8805/3

Code to highest 8805/3

Site: Bleg NOS C49.2

W 11/24/13

[page 2 of 2]
DEFINITIONS
Pathologic Primary Tumor (T)
XX T2 Tumor more than 5 cm in greatest dimension

Regional Lymph Nodes (N)
XX pNX Regional lymph nodes cannot be assessed

The pathologic stage based on available pathologic material is: pT2 pNX
The optimal tissue block for molecular studies on neoplasm is A9
(additional optimal blocks include A10, A13, A14.

Performed by:

As the primary pathologist on this case, I have personally reviewed this
case and edited the report as necessary.

INTERNAL CONSULTATION
This case was seen in consultation with

Patient Release Status:

This result is not viewable by the patient.

Lab and Collection

---SURGICAL PATHOLOGY CONSULTATION--- (Order

Lab and Collection Information

Result History

---SURGICAL PATHOLOGY CONSULTATION--- (Order /

Order Result History Report.

Result Entered By

Lab Information

Lab

Source: NCI Genomic Data Commons file 25034dca-5560-4e4e-a893-aa5db2670e0e (TCGA-X6-A8C4.98E79F47-F1E8-45B0-A717-B3D257FFAFC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).